Somatic mutation profile of tumor specimen TCGA-12-1092-01B (aliquot TCGA-12-1092-01B-01W-0611-08) from TCGA case TCGA-12-1092, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.6 years (21,411 days).
Specimen TCGA-12-1092-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bf47e52-431a-4313-9247-454ecd6394de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1092-10A (Blood Derived Normal), aliquot TCGA-12-1092-10A-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6751daba-2b0f-418a-b1eb-58fd9330369e

The open-access MAF lists 52 somatic variants for this specimen: 45 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 34, Silent 7, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 217/617 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.532C>G p.P178A | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV99635886; called by muse, mutect2
- ADAM29 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756048743, COSV100822071; called by muse, mutect2, varscan2
- AMDHD1 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746321378, COSV57138538; called by muse, mutect2
- ASCC2 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 119/463 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs769624519, COSV100316172, COSV100316331; called by muse, mutect2, varscan2
- ASPHD2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.469); catalogued as rs771541203, COSV53220330; called by muse, mutect2, varscan2
- BTNL8 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1224889478, COSV51456891; called by muse, mutect2, varscan2
- CERS1 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99897347; called by muse, varscan2
- CHL1 | c.2968A>G p.K990E (on ENST00000397491 / NM_001253387.1; = p.K1006E on NM_006614.4) | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99851553; called by muse, mutect2, varscan2
- CNTN2 | c.1942C>G p.P648A | Missense Mutation (SNP) | VAF 132/143 reads (92%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100085199; called by muse, mutect2, varscan2
- CSMD2 | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99055794, COSV99591843; called by muse, mutect2, varscan2
- DNAH5 | c.8311C>T p.R2771C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769557047, COSV54248173; called by muse, mutect2, varscan2
- DNAH8 | c.8943G>A p.W2981* | Nonsense Mutation (SNP) | VAF 213/753 reads (28%) | catalogued as COSV100546064; called by muse, mutect2, varscan2
- DOCK1 | c.1873T>C p.W625R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99730710; called by muse, mutect2, varscan2
- DYSF | c.5771C>T p.S1924F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs777035277, COSV99248253; called by muse, mutect2, varscan2
- EPB41L2 | c.1661-2A>G p.X554_splice | Splice Site (SNP) | VAF 15/183 reads (8%) | catalogued as COSV100440956; called by muse, mutect2
- ERG | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1028107759, COSV55728910, COSV55732583; called by muse, mutect2, varscan2
- GABRE | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 91/164 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs146390765, COSV100944316; called by muse, mutect2, varscan2
- GNAT3 | c.913A>G p.N305D | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.102); catalogued as COSV101242406; called by muse, mutect2, varscan2
- GPI | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.759); catalogued as rs867154141, COSV62893666; called by muse, mutect2, varscan2
- IL6R | c.342dup p.E115Rfs*19 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | catalogued as rs745748718; called by pindel, varscan2
- KYAT3 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99556517; called by muse, mutect2, varscan2
- LMX1A | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 42/154 reads (27%) | catalogued as rs1310771479, COSV54225542; called by muse, mutect2, varscan2
- LRIG1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs147639877, COSV56250668; called by muse, mutect2, varscan2
- MARCHF8 | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV60571491; called by muse, mutect2, varscan2
- MTERF3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs773973185, COSV99749878; called by muse, mutect2, varscan2
- MYH2 | c.1686G>C p.K562N | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99820446; called by muse, mutect2
- NOTCH2 | c.4511+1G>T p.X1504_splice | Splice Site (SNP) | VAF 201/671 reads (30%) | catalogued as COSV99865057; called by muse, mutect2, varscan2
- NPTX2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as rs769298573, COSV55716138; called by muse, mutect2, varscan2
- NRXN3 | c.3079C>T p.R1027C (on ENST00000335750 / NM_001330195.2; = p.R654C on NM_004796.6) | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140301017; called by muse, mutect2
- RIMKLA | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs780592194, COSV101343480, COSV69815364; called by muse, mutect2, varscan2
- RYR2 | c.4930T>G p.L1644V | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100771399; called by muse, mutect2, varscan2
- SLC22A10 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs750659598, COSV100235855; called by muse, mutect2, varscan2
- SLC38A1 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV101284229; called by muse, mutect2, varscan2
- SMR3B | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 29/138 reads (21%) | PolyPhen possibly damaging (0.569); catalogued as COSV100513400, COSV59229034; called by muse, mutect2, varscan2
- SPG7 | c.1294G>C p.E432Q (on ENST00000268704; = p.E439Q on NM_003119.4) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99245064; called by muse, mutect2
- STPG1 | c.29G>A p.R10H (on ENST00000337248 / NM_001199013.2; = p.A3T on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1245180295, COSV50219597; called by muse, mutect2
- SUGP1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs746198171, COSV55920495, COSV99895225; called by muse, mutect2, varscan2
- SUN1 | c.1003C>A p.P335T (on ENST00000405266 / NM_001367651.1; = p.P215T on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100568719, COSV61779329; called by muse, mutect2
- TAF1L | c.4846G>T p.V1616L | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs780116134, COSV99644924; called by muse, mutect2
- TAS2R40 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765436585, COSV101283012; called by muse, mutect2, varscan2
- ZNF609 | c.3835G>C p.A1279P | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV100441319; called by muse, mutect2
- ENTHD1 | c.697del p.W233Gfs*7 | Frame Shift Del (DEL) | VAF 159/634 reads (25%) | called by mutect2, pindel, varscan2
- PTEN | c.897_898dup p.I300Kfs*8 | Frame Shift Ins (INS) | VAF 110/363 reads (30%) | called by mutect2, pindel, varscan2
- RB1 | c.1027_1028del p.L343Sfs*3 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by pindel, varscan2
- AFP | c.1605G>A p.K535= | Silent (SNP) | VAF 101/636 reads (16%) | catalogued as rs762012075, COSV99890125; called by muse, mutect2, varscan2
- AKAP10 | c.300C>T p.A100= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs757341363, COSV56731066, COSV56732905; called by muse, varscan2
- ARNT2 | c.1086C>T p.P362= | Silent (SNP) | VAF 141/846 reads (17%) | catalogued as COSV100309161; called by muse, mutect2, varscan2
- CTNNA2 | c.1590G>A p.E530= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs1397776106, COSV100561278; called by muse, mutect2, varscan2
- GRIN2A | c.3495G>T p.L1165= | Silent (SNP) | VAF 32/440 reads (7%) | catalogued as COSV100410290; called by muse, mutect2
- SERPINA1 | c.303G>T p.L101= | Silent (SNP) | VAF 90/160 reads (56%) | catalogued as COSV100872132; called by muse, mutect2, varscan2
- ZNF460 | c.231G>A p.Q77= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV100828096; called by muse, mutect2, varscan2
